TCGA case TCGA-06-6391 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7a4c0a14-ac97-4c2b-a9cc-68cb561b2494

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Dead; Days to death: 45 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 44.4 years (16,206 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC).
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 45 days; Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-6391-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 1.
  Slide TCGA-06-6391-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-06-6391-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-06-6391-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-6391-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Patient had prior breast malignancy with systemic radiation.
- Prior malignancy: Prior Breast Cancer as per pathology report treatment not specified.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 45 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 45 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 45 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-06-6391-01): tumor purity 0.39, ploidy 2.19, whole-genome doublings 0 (call status: maf_call).
